Somatic mutation profile of tumor specimen MMRF_1758_1_BM_CD138pos (aliquot MMRF_1758_1_BM_CD138pos_T1_KBS5U_L04787) from MMRF case MMRF_1758, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.5 years (26,473 days).
Specimen MMRF_1758_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b77d8fe5-f6eb-4e1a-a0d5-2e41597f4802.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1758_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1758_1_PB_Whole_C3_KBS5U_L04800; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79a69a4b-955f-41dd-8221-0aee71c2de27

The open-access MAF lists 188 somatic variants for this specimen: 73 protein-altering or splice-affecting, 24 silent, 91 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, 3'UTR 50, Silent 24, Intron 22, 5'UTR 8, Nonsense Mutation 8, RNA 6, 3'Flank 3, 5'Flank 2, Frame Shift Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.3722G>A p.R1241H | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs535746029; called by muse, mutect2, varscan2
- ACKR2 | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 94/267 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757492481; called by muse, mutect2, varscan2
- C19orf81 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs530632779; called by muse, mutect2, varscan2
- CDH10 | c.406A>T p.T136S | Missense Mutation (SNP) | VAF 155/532 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.486); catalogued as COSV100052845; called by muse, mutect2, varscan2
- CLEC12B | c.190T>C p.F64L | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT tolerated (0.25); PolyPhen benign (0.303); catalogued as COSV58862665; called by muse, mutect2, varscan2
- COL22A1 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.935); catalogued as COSV57335612; called by muse, mutect2, varscan2
- COL27A1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.059); catalogued as rs750538488; called by muse, mutect2, varscan2
- COL5A1 | c.537G>C p.L179F | Missense Mutation (SNP) | VAF 56/237 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs773918199; called by muse, mutect2, varscan2
- DUSP2 | c.638T>C p.F213S | Missense Mutation (SNP) | VAF 80/265 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1382087825; called by muse, mutect2, varscan2
- ETNPPL | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 58/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56594938; called by muse, mutect2, varscan2
- FAM170A | c.7C>T p.R3* | Nonsense Mutation (SNP) | VAF 57/278 reads (21%) | catalogued as rs904773139, COSV58925726; called by muse, mutect2, varscan2
- FFAR4 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs373550620; called by muse, mutect2, varscan2
- FGF11 | c.609G>A p.V203= | Splice Region (SNP) | VAF 101/208 reads (49%) | catalogued as rs772998713, COSV99548379; called by muse, mutect2, varscan2
- GREM2 | c.504G>T p.Q168H | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV58949807; called by muse, mutect2, varscan2
- LRP2 | c.6916G>T p.E2306* | Nonsense Mutation (SNP) | VAF 105/318 reads (33%) | catalogued as COSV55546489; called by muse, mutect2, varscan2
- MICAL2 | c.2852C>T p.T951M | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); catalogued as rs765434957, COSV56322217; called by muse, mutect2, varscan2
- MYMK | c.445G>A p.V149I | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs780606963, COSV60601648; called by muse, mutect2, varscan2
- NEB | c.2131G>T p.E711* | Nonsense Mutation (SNP) | VAF 12/224 reads (5%) | catalogued as COSV99415898; called by muse, mutect2
- NEDD1 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 65/140 reads (46%) | catalogued as COSV57144934; called by muse, mutect2, varscan2
- PLXNB2 | c.2422-1G>T p.X808_splice | Splice Site (SNP) | VAF 45/99 reads (45%) | catalogued as rs1456561902; called by muse, mutect2, varscan2
- PNPT1 | c.174A>G p.I58M | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as rs746769778; called by muse, mutect2, varscan2
- PRDM1 | c.1763C>G p.S588C | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100958738; called by muse, mutect2, varscan2
- RAPGEF1 | c.470G>A p.R157Q | Missense Mutation (SNP) | VAF 110/382 reads (29%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.996); catalogued as rs1309335863; called by muse, mutect2, varscan2
- STYXL2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs139568726; called by muse, mutect2, varscan2
- THADA | c.1748C>A p.P583Q | Missense Mutation (SNP) | VAF 88/248 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV57679540; called by muse, mutect2, varscan2
- TNRC6B | c.3643G>A p.V1215M (on ENST00000454349 / NM_001162501.2; = p.V1105M on NM_015088.3) | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs748167158, COSV57292114; called by muse, mutect2, varscan2
- TYW1 | c.1669C>A p.L557I | Missense Mutation (SNP) | VAF 8/133 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.119); catalogued as COSV100658721; called by muse, mutect2
- ZC3H13 | c.1675C>T p.R559* | Nonsense Mutation (SNP) | VAF 44/326 reads (13%) | catalogued as COSV54455248; called by muse, mutect2, varscan2
- ZKSCAN4 | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.174); catalogued as rs1037478018; called by muse, mutect2, varscan2
- APH1B | c.407C>A p.T136N | Missense Mutation (SNP) | VAF 122/273 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- AUH | c.919A>G p.I307V | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- BCL11B | c.485C>A p.P162H | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- C8G | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CCNP | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 48/134 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- COG8 | c.865T>C p.Y289H | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A1 | c.1217C>G p.P406R | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- CXCR5 | c.125A>G p.E42G | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- DSEL | c.686A>T p.Q229L | Missense Mutation (SNP) | VAF 84/178 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- EIF3A | c.1704C>G p.I568M | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); called by muse, mutect2
- EPC1 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 51/80 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FCHO2 | c.2407A>T p.T803S | Missense Mutation (SNP) | VAF 95/182 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- FYB2 | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.067); called by muse, mutect2
- GOT1 | c.374A>C p.N125T | Missense Mutation (SNP) | VAF 50/165 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GRIFIN | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.97); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- HMCN1 | c.1994C>G p.T665S | Missense Mutation (SNP) | VAF 50/72 reads (69%) | SIFT tolerated (0.11); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- HNRNPA3 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- IARS2 | c.177A>T p.R59S | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV2-70D | c.171G>C p.W57C | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- IL7R | c.149G>A p.G50E | Missense Mutation (SNP) | VAF 126/537 reads (23%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MROH2B | c.1211C>A p.A404E | Missense Mutation (SNP) | VAF 68/482 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- MYO7B | c.3092C>T p.A1031V | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTCHD4 | c.546T>A p.Y182* | Nonsense Mutation (SNP) | VAF 44/158 reads (28%) | called by muse, mutect2, varscan2
- RBMX | c.446T>A p.V149E | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.556); called by muse, varscan2
- RCN1 | c.933G>A p.M311I | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SEC24A | c.2453T>G p.I818S | Missense Mutation (SNP) | VAF 123/252 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHMT1 | c.1300C>A p.Q434K | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- SKOR2 | c.1091C>G p.A364G | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.578); called by muse, varscan2
- SLC6A15 | c.791T>C p.V264A | Missense Mutation (SNP) | VAF 117/247 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- SMCHD1 | c.5611G>T p.G1871* | Nonsense Mutation (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- SMS | c.710G>T p.C237F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- TCHH | c.1960A>G p.R654G | Missense Mutation (SNP) | VAF 188/285 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- TENT5C | c.286del p.H96Mfs*22 | Frame Shift Del (DEL) | VAF 11/94 reads (12%) | called by mutect2, pindel, varscan2
- UNC13A | c.3601G>T p.E1201* | Nonsense Mutation (SNP) | VAF 14/104 reads (13%) | called by muse, mutect2, varscan2
- WASHC4 | c.1547T>C p.I516T | Missense Mutation (SNP) | VAF 87/169 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- WDR87 | c.3043C>A p.L1015I | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.767); called by muse, mutect2
- ZMYM3 | c.264A>C p.K88N | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ZNF382 | c.281A>G p.Q94R | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF449 | c.1537C>T p.H513Y | Missense Mutation (SNP) | VAF 78/200 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- ZNF451 | c.1955A>G p.Y652C | Missense Mutation (SNP) | VAF 66/237 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF474 | c.869G>A p.C290Y | Missense Mutation (SNP) | VAF 95/404 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF511 | c.436T>C p.C146R | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ZNF835 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.055); called by muse, mutect2
- ZXDC | c.2066C>G p.P689R | Missense Mutation (SNP) | VAF 108/292 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- ADAM22 | c.168C>T p.I56= | Silent (SNP) | VAF 56/169 reads (33%) | called by muse, mutect2, varscan2
- BAHCC1 | c.663C>A p.G221= | Silent (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2
- BCL9 | c.3465C>T p.H1155= | Silent (SNP) | VAF 42/127 reads (33%) | called by muse, mutect2, varscan2
- CDC42EP2 | c.141C>T p.G47= | Silent (SNP) | VAF 72/217 reads (33%) | catalogued as rs778016505; called by muse, mutect2, varscan2
- CDH12 | c.2229G>A p.G743= | Silent (SNP) | VAF 110/413 reads (27%) | catalogued as rs1161859677, COSV101203419; called by muse, mutect2, varscan2
- DOCK4 | c.5787C>T p.P1929= | Silent (SNP) | VAF 12/181 reads (7%) | called by muse, mutect2
- EPS8L3 | c.222C>T p.D74= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs766290475; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAT1 | c.13707C>T p.D4569= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs745595921, COSV71674460; called by muse, mutect2, varscan2
- GMPR | c.537A>G p.G179= | Silent (SNP) | VAF 56/158 reads (35%) | called by muse, mutect2, varscan2
- GPR180 | c.1281A>C p.P427= | Silent (SNP) | VAF 99/195 reads (51%) | called by muse, mutect2, varscan2
- IGKV2-24 | c.297A>G p.K99= | Silent (SNP) | VAF 42/192 reads (22%) | catalogued as rs1361467667; called by muse, mutect2, varscan2
- ITPR1 | c.2613T>C p.A871= (on ENST00000354582; = p.A856= on NM_002222.7) | Silent (SNP) | VAF 39/109 reads (36%) | called by muse, mutect2, varscan2
- KLF10 | c.369A>G p.S123= | Silent (SNP) | VAF 29/140 reads (21%) | called by muse, mutect2, varscan2
- MAMSTR | c.618G>A p.A206= (on ENST00000318083 / NM_001130915.2; = p.A103= on NM_182574.2) | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs755562142; called by muse, mutect2, varscan2
- NR2E1 | c.279G>A p.G93= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as rs769686347; called by muse, mutect2, varscan2
- NRXN3 | c.1539C>T p.L513= (on ENST00000335750 / NM_001330195.2; = p.L140= on NM_004796.6) | Silent (SNP) | VAF 36/89 reads (40%) | catalogued as rs368322773; called by muse, mutect2, varscan2
- OBSCN | c.12324G>A p.E4108= | Silent (SNP) | VAF 72/105 reads (69%) | called by muse, mutect2, varscan2
- OR5D14 | c.594C>T p.H198= | Silent (SNP) | VAF 124/449 reads (28%) | catalogued as rs766784156; called by muse, mutect2, varscan2
- PCDHA6 | c.123C>T p.H41= | Silent (SNP) | VAF 42/150 reads (28%) | catalogued as COSV65353922; called by muse, mutect2, varscan2
- PRAG1 | c.3588C>A p.A1196= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100422988; called by muse, mutect2, varscan2
- RAPGEF2 | c.4416C>T p.N1472= | Silent (SNP) | VAF 38/72 reads (53%) | catalogued as rs573018319; called by muse, mutect2, varscan2
- SEC14L5 | c.1710C>T p.S570= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs200042173, COSV52039356; called by muse, mutect2, varscan2
- UBE2V1 | c.9C>T p.A3= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs757711194; called by muse, mutect2, varscan2
- ZNF292 | c.2379T>G p.A793= | Silent (SNP) | VAF 18/141 reads (13%) | called by muse, mutect2, varscan2
- AC069528.1 | n.500C>T | RNA (SNP) | VAF 20/70 reads (29%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+5611C>T | Intron (SNP) | VAF 85/177 reads (48%) | called by muse, mutect2, varscan2
- AFAP1 | c.*4502A>T | 3'UTR (SNP) | VAF 56/109 reads (51%) | called by muse, mutect2, varscan2
- AIG1 | c.*15A>T | 3'UTR (SNP) | VAF 28/366 reads (8%) | called by muse, mutect2
- AKNA | c.*253C>T | 3'UTR (SNP) | VAF 64/278 reads (23%) | catalogued as rs532011692; called by muse, mutect2, varscan2
- ALDH1A3 | c.99+357_99+388del | Intron (DEL) | VAF 20/106 reads (19%) | called by mutect2, pindel, varscan2
- AP002414.4 | n.571C>T | RNA (SNP) | VAF 15/36 reads (42%) | catalogued as rs1190650926; called by muse, mutect2, varscan2
- ATXN7L1 | c.*2523A>T | 3'UTR (SNP) | VAF 38/131 reads (29%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021136 T>C | 5'Flank (SNP) | VAF 109/112 reads (97%) | catalogued as rs552023208; called by muse, mutect2, varscan2
- BLOC1S2 | c.*9T>C | 3'UTR (SNP) | VAF 146/474 reads (31%) | catalogued as rs1234290816, COSV100951801; called by muse, mutect2, varscan2
- BMPER | c.*1645C>T | 3'UTR (SNP) | VAF 46/110 reads (42%) | called by muse, mutect2, varscan2
- C5orf66-AS2 | n.775G>A | RNA (SNP) | VAF 34/145 reads (23%) | catalogued as rs543875187; called by muse, mutect2, varscan2
- CCDC121P1 | n.809C>G | RNA (SNP) | VAF 107/174 reads (61%) | called by muse, mutect2, varscan2
- CCNJ | c.*1085G>A | 3'UTR (SNP) | VAF 36/99 reads (36%) | called by muse, mutect2, varscan2
- CCT4 | c.*190G>C | 3'UTR (SNP) | VAF 9/121 reads (7%) | called by muse, mutect2
- CDC23 | c.*223A>C | 3'UTR (SNP) | VAF 23/100 reads (23%) | called by muse, mutect2, varscan2
- CDH19 | c.*1655A>G | 3'UTR (SNP) | VAF 43/84 reads (51%) | called by muse, mutect2, varscan2
- CDK10 | c.87+795C>G | Intron (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- CDK8 | c.*469T>C | 3'UTR (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
- CISD2 | c.104-90A>T | Intron (SNP) | VAF 21/422 reads (5%) | called by muse, mutect2
- CMTM6 | c.*1979G>A | 3'UTR (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
- CORT | c.-185G>A | 5'UTR (SNP) | VAF 26/200 reads (13%) | catalogued as rs780645425, COSV100259211; called by muse, mutect2, varscan2
- CSPP1 | c.3077-1061_3077-1060del | Intron (DEL) | VAF 46/83 reads (55%) | called by mutect2, pindel, varscan2
- CXCL12 | c.*675C>A | 3'UTR (SNP) | VAF 129/196 reads (66%) | called by muse, mutect2, varscan2
- DAPK1 | c.*363T>C | 3'UTR (SNP) | VAF 118/239 reads (49%) | catalogued as rs1016642878; called by muse, mutect2, varscan2
- DIP2A | c.*945G>A | 3'UTR (SNP) | VAF 32/64 reads (50%) | called by muse, mutect2, varscan2
- DLG4 | c.96+42G>T | Intron (SNP) | VAF 38/86 reads (44%) | called by muse, mutect2, varscan2
- DMD | c.*955T>G | 3'UTR (SNP) | VAF 43/118 reads (36%) | catalogued as rs865872761; called by muse, mutect2, varscan2
- DMXL1 | c.*1542G>T | 3'UTR (SNP) | VAF 50/180 reads (28%) | called by muse, mutect2, varscan2
- E2F8 | c.*129C>T | 3'UTR (SNP) | VAF 65/194 reads (34%) | called by muse, mutect2, varscan2
- ESYT2 | chr7:158732129 A>G | 3'Flank (SNP) | VAF 7/113 reads (6%) | called by muse, mutect2
- FAM102A | c.-272C>T | 5'UTR (SNP) | VAF 29/121 reads (24%) | called by muse, mutect2, varscan2
- FCRL5 | c.1681+2270C>T | Intron (SNP) | VAF 45/175 reads (26%) | called by muse, mutect2, varscan2
- FOXA2 | c.*224A>G | 3'UTR (SNP) | VAF 45/109 reads (41%) | called by muse, mutect2, varscan2
- FTSJ1 | c.958-73A>C | Intron (SNP) | VAF 101/271 reads (37%) | called by muse, mutect2, varscan2
- GDF6 | c.*1949A>C | 3'UTR (SNP) | VAF 116/178 reads (65%) | called by muse, mutect2, varscan2
- GGA2 | c.*255C>A | 3'UTR (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- GPR135 | c.*2234G>A | 3'UTR (SNP) | VAF 14/155 reads (9%) | called by muse, mutect2
- GRIN2A | c.*962G>A | 3'UTR (SNP) | VAF 42/75 reads (56%) | catalogued as rs530650621, COSV58043767; called by muse, mutect2, varscan2
- GSTM3 | c.-123A>C | 5'UTR (SNP) | VAF 42/82 reads (51%) | called by muse, mutect2, varscan2
- HDAC11 | c.*559C>T | 3'UTR (SNP) | VAF 38/143 reads (27%) | called by muse, mutect2, varscan2
- HHIPL2 | c.-53G>A | 5'UTR (SNP) | VAF 22/248 reads (9%) | called by muse, mutect2
- IGF2BP2 | c.240-18094G>A | Intron (SNP) | VAF 22/62 reads (35%) | called by mutect2, varscan2
- IL7R | c.*2031T>C | 3'UTR (SNP) | VAF 34/147 reads (23%) | called by muse, mutect2, varscan2
- ITGAV | c.*658A>T | 3'UTR (SNP) | VAF 35/108 reads (32%) | called by muse, mutect2, varscan2
- KCNJ9 | c.*78A>T | 3'UTR (SNP) | VAF 4/44 reads (9%) | catalogued as rs1289820529, COSV58758158; called by muse, mutect2
- KIF21B | chr1:200970820 C>A | 3'Flank (SNP) | VAF 34/138 reads (25%) | called by muse, mutect2, varscan2
- KLF2 | c.-63C>T | 5'UTR (SNP) | VAF 27/83 reads (33%) | called by muse, mutect2, varscan2
- KLF7 | c.*1005C>T | 3'UTR (SNP) | VAF 40/125 reads (32%) | catalogued as rs1055040548; called by muse, mutect2, varscan2
- KPNA4 | c.*2625C>T | 3'UTR (SNP) | VAF 60/174 reads (34%) | catalogued as rs1194336501; called by mutect2, varscan2
- KRBOX1 | c.-46-563G>A | Intron (SNP) | VAF 24/306 reads (8%) | called by muse, mutect2
- LARS2 | c.*698G>A | 3'UTR (SNP) | VAF 36/119 reads (30%) | catalogued as rs143901188; called by muse, mutect2, varscan2
- LINC01553 | n.2859A>G | RNA (SNP) | VAF 45/129 reads (35%) | called by muse, mutect2, varscan2
- LPA | c.*143T>C | 3'UTR (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- LRRN1 | c.*620A>C | 3'UTR (SNP) | VAF 50/75 reads (67%) | called by muse, mutect2, varscan2
- LTC4S | c.*92C>G | 3'UTR (SNP) | VAF 31/62 reads (50%) | called by muse, mutect2, varscan2
- MAP4K4 | chr2:101893056 C>T | 3'Flank (SNP) | VAF 158/519 reads (30%) | called by muse, mutect2, varscan2
- MRNIP | c.538-508G>A | Intron (SNP) | VAF 48/84 reads (57%) | catalogued as rs917462672; called by muse, mutect2, varscan2
- MSMB | chr10:46046322 C>T | 5'Flank (SNP) | VAF 191/615 reads (31%) | catalogued as rs536574316; called by muse, mutect2, varscan2
- NELFCD | c.340+48A>T | Intron (SNP) | VAF 10/75 reads (13%) | called by muse, mutect2, varscan2
- NME9 | c.-473C>G | 5'UTR (SNP) | VAF 14/75 reads (19%) | catalogued as rs1388500834; called by muse, mutect2, varscan2
- NPC1 | c.3754+140T>A | Intron (SNP) | VAF 5/40 reads (13%) | catalogued as COSV99340443; called by muse, varscan2
- NTRK2 | c.1397-55087T>C | Intron (SNP) | VAF 44/192 reads (23%) | called by muse, mutect2, varscan2
- PAK5 | c.*1014C>G | 3'UTR (SNP) | VAF 51/190 reads (27%) | catalogued as rs915966735; called by muse, mutect2, varscan2
- PDE10A | c.*1294T>G | 3'UTR (SNP) | VAF 37/89 reads (42%) | called by muse, mutect2, varscan2
- PET100 | c.139-64_139-61delinsGGC | Intron (DEL) | VAF 4/28 reads (14%) | called by pindel, varscan2*
- PHF2 | c.*501T>A | 3'UTR (SNP) | VAF 34/134 reads (25%) | called by muse, mutect2, varscan2
- PHOSPHO1 | c.-63G>A | 5'UTR (SNP) | VAF 65/143 reads (45%) | catalogued as rs551956705, COSV56799300; called by muse, mutect2, varscan2
- PLCB4 | c.*110A>C | 3'UTR (SNP) | VAF 235/365 reads (64%) | called by muse, mutect2, varscan2
- PLIN1 | c.*1211C>G | 3'UTR (SNP) | VAF 28/120 reads (23%) | called by muse, mutect2, varscan2
- PLOD2 | c.*760C>A | 3'UTR (SNP) | VAF 64/234 reads (27%) | called by muse, mutect2, varscan2
- PTS | c.186+192G>A | Intron (SNP) | VAF 72/203 reads (35%) | called by muse, mutect2, varscan2
- PVR | c.*774C>T | 3'UTR (SNP) | VAF 23/140 reads (16%) | called by muse, mutect2, varscan2
- RAD21 | c.1471-225T>C | Intron (SNP) | VAF 38/135 reads (28%) | called by muse, mutect2, varscan2
- RASAL1 | c.*516C>T | 3'UTR (SNP) | VAF 138/141 reads (98%) | called by muse, varscan2
- RBM39 | c.1226-733_1226-715del | Intron (DEL) | VAF 23/138 reads (17%) | called by mutect2, pindel, varscan2
- RGCC | c.-143_-123del | 5'UTR (DEL) | VAF 17/40 reads (43%) | called by mutect2, pindel, varscan2
- RHOU | c.*330C>T | 3'UTR (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- RPS2 | c.709+106C>T | Intron (SNP) | VAF 38/99 reads (38%) | catalogued as rs1374714840, COSV99238841; called by muse, mutect2, varscan2
- SECISBP2 | c.*528T>C | 3'UTR (SNP) | VAF 52/190 reads (27%) | called by muse, mutect2, varscan2
- SH3BP5 | c.*1244T>C | 3'UTR (SNP) | VAF 18/50 reads (36%) | called by muse, varscan2
- SPATA8 | n.1202G>C | RNA (SNP) | VAF 20/326 reads (6%) | called by muse, mutect2
- SPEN | c.*59dup | 3'UTR (INS) | VAF 110/223 reads (49%) | called by mutect2, pindel, varscan2
- SPOCK2 | c.*1683G>A | 3'UTR (SNP) | VAF 47/148 reads (32%) | catalogued as rs751825142; called by muse, mutect2, varscan2
- SPRY3 | c.*788G>A | 3'UTR (SNP) | VAF 114/287 reads (40%) | called by muse, mutect2, varscan2
- TADA3 | c.565-481C>T | Intron (SNP) | VAF 360/569 reads (63%) | called by muse, mutect2, varscan2
- TMEM154 | c.479-14T>G | Intron (SNP) | VAF 22/34 reads (65%) | called by muse, mutect2, varscan2
- TMEM170B | c.*6393G>A | 3'UTR (SNP) | VAF 22/213 reads (10%) | called by muse, mutect2, varscan2
- TMPRSS6 | c.1196+108G>T | Intron (SNP) | VAF 17/32 reads (53%) | called by muse, mutect2, varscan2
- TRIM10 | c.*426A>G | 3'UTR (SNP) | VAF 15/152 reads (10%) | called by muse, mutect2, varscan2
- TSLP | c.*1655T>C | 3'UTR (SNP) | VAF 79/173 reads (46%) | called by muse, mutect2, varscan2
